Gene-level copy-number profile of tumor specimen TCGA-J9-A52B-01A from TCGA case TCGA-J9-A52B, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.6 years (22,849 days).
Specimen TCGA-J9-A52B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.4f6638d6-ca70-41a5-a3f6-8434a36385dd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-J9-A52B-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ae83bc51-d257-4a35-926c-51bfbf253608

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 1,190; copy number 2: 5,232; copy number 3: 20,213; copy number 4: 32,321; copy number 5: 669; copy number 6: 177.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-J9-A52B-01A-11D-A26L-01): tumor purity 0.69, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:37,593,977–38,333,421, 12 genes: AP001407.1, KCNJ6, KCNJ6-AS1, DSCR4, DSCR4-IT1, DSCR8, KCNJ15, AP001425.1, DSCR10, AP001434.1, SPATA20P1, LINC01423.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 949. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
